Somatic mutation profile of tumor specimen MP2PRT-PAVYFY-TMP1-A (aliquot MP2PRT-PAVYFY-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAVYFY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,880 days).
Specimen MP2PRT-PAVYFY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 597f6519-c30c-48cc-ac7b-171acaba156f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVYFY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVYFY-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/655c1627-a95c-4370-b4c9-04b62bba457a

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 94/246 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BMS1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 159/360 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs763463745; called by muse, mutect2, varscan2
- DNAH3 | c.4114C>T p.R1372C | Missense Mutation (SNP) | VAF 293/537 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs371228106; called by muse, mutect2, varscan2
- MYH13 | c.4078G>A p.E1360K | Missense Mutation (SNP) | VAF 182/531 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs371382799, COSV52822284; called by muse, mutect2
- MYT1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 182/446 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as rs1347895535; called by muse, mutect2, varscan2
- NCKAP5 | c.4231C>T p.R1411C | Missense Mutation (SNP) | VAF 193/459 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200882141, COSV58427315; called by muse, mutect2, varscan2
- RMC1 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 22/315 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs957858635; called by muse, mutect2
- APBB1IP | c.1797_1805del p.P604_P606del | In Frame Del (DEL) | VAF 37/137 reads (27%) | called by mutect2, pindel, varscan2
- HOXA4 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 122/297 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.12956G>C p.G4319A | Missense Mutation (SNP) | VAF 177/453 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- KLHL32 | c.194A>T p.D65V | Missense Mutation (SNP) | VAF 95/243 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MSI2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PEX5L | c.845A>T p.K282M | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP40 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- ADCYAP1R1 | c.180C>T p.N60= | Silent (SNP) | VAF 119/299 reads (40%) | called by muse, mutect2, varscan2
- ASZ1 | c.9G>A p.A3= | Silent (SNP) | VAF 110/303 reads (36%) | catalogued as rs1296162068, COSV52914346; called by muse, mutect2, varscan2
- ERMARD | c.1521-79G>A | Intron (SNP) | VAF 173/497 reads (35%) | catalogued as rs534588719; called by muse, mutect2, varscan2
